Somatic mutation profile of tumor specimen 0DIW7R from CCDI case PBBVUA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 15.2 years (5,542 days).
Specimen 0DIW7R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ec5e0ac-5db9-4f8a-8209-1f8f544a652b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIW63 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab3c4cbd-b0e3-4f40-94f5-d59f2c36c951

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD163 | c.2720C>A p.S907* | Nonsense Mutation (SNP) | VAF 50/1034 reads (5%) | catalogued as COSV63137159; called by muse, mutect2
- CEP162 | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 135/694 reads (19%) | catalogued as rs1413364753, COSV100002366; called by muse, mutect2, varscan2
- AC009779.3 | c.*2522C>A | 3'UTR (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
